MMRF case MMRF_2559 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/01a01acf-ed76-4f04-ad6a-2e66f29754dc

Demographics
Sex at birth: male; Race: white; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.9 years (18,945 days); Days to last known disease status: 632 days (1.7 years); Days to last follow up: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 131 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 275 days; Days to treatment end: 410 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 410 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.5 mg/dL; Immunoglobulin G 2.88 g/L; Immunoglobulin A 63.2 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 10.1 g/dL; Glucose 6.22 mmol/L.
- Day 92 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 162: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.82 ×10⁹/L; Platelets 328 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.71 mmol/L.
- Day 275: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 373 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 9.09 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.52 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 8 g/dL; Glucose 4.73 mmol/L.
- Day 457 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 9.15 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.57 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.
- Day 548 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.53 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 632: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day 1: Weight: 92 kg; Height: 191 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2559_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2559_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
